TCGA case TCGA-A6-A56B — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74a0264d-1d31-430d-9a88-e7334c8aa96c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Dead; Days to death: 1,711 days (4.7 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 57.2 years (20,903 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,711 days (4.7 years).
   Pathology details: Circumferential resection margin: 15; Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 25; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Vascular invasion present: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab; Days to treatment start: 82 days; Days to treatment end: 243 days; Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 82 days; Days to treatment end: 110 days; Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 82 days; Days to treatment end: 238 days; Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 82 days; Days to treatment end: 236 days; Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 82 days; Days to treatment end: 236 days; Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 61.8 years (22,581 days); Days to diagnosis: 1,678 days (4.6 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Days to follow up: 1,595 days (4.4 years); Disease response: Tumor Free.
- Day 1,678 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,678 days (4.6 years).
- Days to follow up: 1,711 days (4.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 13.2 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 77.2 kg; Height: 180 cm; BMI: 23.8.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-A56B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 410 mg.
  Slide TCGA-A6-A56B-01A-03-TS3: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 17; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A6-A56B-01A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A6-A56B-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-A56B-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 13.2; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: Yes; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,711 days; disease-specific survival: no event (censored), 1,711 days; disease-free interval: event (new tumor event after initially disease-free), 1,678 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,678 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-A56B-01A-31D-A28F-01): tumor purity 0.72, ploidy 3.21, whole-genome doublings 1.
